Somatic mutation profile of tumor specimen TCGA-D3-A51E-06A (aliquot TCGA-D3-A51E-06A-11D-A25O-08) from TCGA case TCGA-D3-A51E, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 46.0 years (16,788 days).
Specimen TCGA-D3-A51E-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f261cedd-60f7-447a-af71-2bda48f628d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51E-10A (Blood Derived Normal), aliquot TCGA-D3-A51E-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fb39c0b-da43-430e-8445-6034a0ef6b8e

The open-access MAF lists 325 somatic variants for this specimen: 219 protein-altering or splice-affecting, 102 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 102, Nonsense Mutation 20, Frame Shift Del 4, Splice Site 2, Intron 1, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEN1 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | catalogued as rs1114167477, COSV53640111, COSV53643457; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 105/161 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14708T>A p.V4903D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV68943078; called by muse, mutect2, varscan2
- ABCA7 | c.5282C>A p.P1761H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV54023666; called by muse, mutect2, varscan2
- ACAN | c.4504G>A p.G1502R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs748195726, COSV61355447; called by muse, mutect2
- ACER1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56834607; called by muse, mutect2, varscan2
- ACTRT2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372578612, COSV65758827; called by muse, mutect2, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, mutect2, varscan2
- ADAMTS18 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51398404; called by muse, mutect2, varscan2
- AK7 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs911976559, COSV50869069; called by muse, mutect2, varscan2
- ALDH3A1 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV56734007; called by muse, mutect2, varscan2
- ALG9 | c.1676T>C p.I559T (on ENST00000614444 / NM_001352418.1; = p.I566T on NM_024740.2) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67643408; called by muse, mutect2, varscan2
- ALOX5 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.018); catalogued as COSV65550860; called by muse, mutect2, varscan2
- AMPD3 | c.911C>T p.P304L (on ENST00000396553 / NM_001025389.2; = p.P313L on NM_000480.3) | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV67329834; called by muse, mutect2, varscan2
- ANO5 | c.2140A>T p.T714S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV61081809; called by muse, mutect2, varscan2
- APBB2 | c.1394G>T p.G465V (on ENST00000295974 / NM_001166050.2; = p.G466V on NM_004307.2) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99922671; called by muse, mutect2, varscan2
- APBB2 | c.1393G>A p.G465R (on ENST00000295974 / NM_001166050.2; = p.G466R on NM_004307.2) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99922675; called by muse, mutect2, varscan2
- APBB2 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1165147429, COSV55946739; called by muse, mutect2, varscan2
- APOBEC2 | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55107278; called by muse, mutect2, varscan2
- APOL3 | c.1150G>A p.E384K (on ENST00000349314 / NM_145640.2; = p.E313K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV62579086; called by muse, mutect2, varscan2
- ARHGAP12 | c.2351T>G p.F784C | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60961028, COSV60966173; called by muse, mutect2, varscan2
- ARHGAP5 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1338758649, COSV61533685; called by muse, mutect2, varscan2
- ARHGEF10L | c.3175C>T p.L1059F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV51427425; called by muse, mutect2, varscan2
- ASIC5 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV73332547; called by muse, mutect2, varscan2
- ASXL2 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV55453068; called by muse, mutect2, varscan2
- ATF7IP2 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV61092116; called by muse, mutect2, varscan2
- ATP6V0D1 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52096693; called by muse, mutect2, varscan2
- B4GALNT2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs375918507, COSV55924564; called by muse, mutect2, varscan2
- BCR | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1288831062, COSV59926197; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3644C>T p.A1215V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767150364, COSV63243840; called by muse, mutect2, varscan2
- BRCA2 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV66447811; called by muse, mutect2, varscan2
- C1orf127 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 31/67 reads (46%) | catalogued as COSV65436564; called by muse, mutect2, varscan2
- C4B | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs767540386, COSV70313250; called by muse, mutect2, varscan2
- CAMK2A | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1160671001, COSV62244965, COSV62245410; called by muse, mutect2, varscan2
- CAPZA3 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV56848576; called by muse, mutect2, varscan2
- CASP8AP2 | c.4391C>T p.S1464L | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1450630249, COSV52745029; called by muse, mutect2, varscan2
- CCDC51 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56486526; called by muse, mutect2, varscan2
- CCDC54 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs773404407, COSV53757909; called by muse, mutect2, varscan2
- CCN4 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781544299, COSV51529294, COSV51530489; called by muse, mutect2, varscan2
- CDC40 | c.983T>C p.F328S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57007709; called by muse, mutect2, varscan2
- CDCP2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.636); catalogued as rs753051915, COSV61282463; called by muse, mutect2, varscan2
- CDH10 | c.916T>A p.Y306N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52569225; called by muse, mutect2, varscan2
- CECR2 | c.2305C>T p.P769S (on ENST00000342247 / NM_001290047.2; = p.P586S on NM_001290046.1) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs753849827, COSV52835685; called by muse, mutect2
- CHD1 | c.3695C>T p.P1232L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV52336538; called by muse, mutect2, varscan2
- CHGB | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.056); catalogued as rs778423183, COSV66759541; called by muse, mutect2
- CHRM2 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV57764934, COSV57779645; called by muse, mutect2, varscan2
- CNTN4 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199542195, COSV68561856; called by muse, mutect2, varscan2
- COCH | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV53549644; called by muse, mutect2, varscan2
- COL5A2 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs766119748, COSV66406860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.2822G>A p.G941E (on ENST00000651564; = p.G894E on NM_015692.5) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as COSV71595738; called by muse, mutect2, varscan2
- CRNN | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 157/287 reads (55%) | catalogued as COSV55120622; called by muse, mutect2, varscan2
- CRY2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV69887976; called by muse, mutect2, varscan2
- CTSO | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70808803; called by muse, mutect2, varscan2
- DACH1 | c.1523C>T p.P508L (on ENST00000619232 / NM_001366712.1; = p.P456L on NM_080759.6) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV57488602; called by muse, mutect2, varscan2
- DACH1 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.175); catalogued as COSV57488621; called by muse, mutect2, varscan2
- DAO | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs764973777, COSV57322547; called by muse, mutect2, varscan2
- DCTN1 | c.3547G>A p.A1183T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as rs886056329, COSV62619558; called by muse, mutect2
- DDX46 | c.1575T>G p.Y525* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV62798377; called by muse, mutect2, varscan2
- DISP3 | c.3470G>A p.G1157D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53819825; called by muse, mutect2, varscan2
- DMBT1 | c.6541G>A p.D2181N (on ENST00000338354 / NM_001377530.1; = p.D1424N on NM_004406.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as rs1263207614, COSV57533595; called by muse, mutect2, varscan2
- DNAH11 | c.10492C>T p.P3498S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60938421; called by muse, mutect2, varscan2
- DNAH9 | c.10001G>T p.C3334F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV52332778; called by muse, mutect2, varscan2
- DOCK3 | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.348); catalogued as COSV56501708; called by muse, mutect2, varscan2
- DRD5 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs1434044656, COSV58576640, COSV58580262; called by muse, mutect2, varscan2
- DSC2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV51860941; called by muse, mutect2, varscan2
- DSCAM | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV68020359; called by muse, mutect2, varscan2
- DSE | c.2794C>T p.Q932* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV59061591; called by muse, mutect2, varscan2
- ELAVL2 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs146832864, COSV99806413; called by muse, mutect2, varscan2
- ENGASE | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs748662225, COSV56133850; called by muse, mutect2, varscan2
- ENTHD1 | c.102T>G p.S34R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57317009; called by muse, mutect2, varscan2
- EP400 | c.9178A>G p.T3060A | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.069); catalogued as COSV57762125; called by muse, mutect2, varscan2
- EPPK1 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554661150, COSV73260761; called by muse, mutect2
- FAM135A | c.2573C>T p.S858F (on ENST00000370479 / NM_001351599.1; = p.S645F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV52047602; called by muse, mutect2, varscan2
- FAM135B | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867471938, COSV52703558; called by muse, mutect2, varscan2
- FAM135B | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs750908660, COSV52703573, COSV52705631; called by muse, mutect2, varscan2
- FAM222B | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs746524449, COSV57927482; called by muse, mutect2, varscan2
- FANCM | c.2614C>T p.H872Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57497058; called by muse, mutect2, varscan2
- FAT3 | c.2692G>A p.A898T | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as rs1477803761, COSV53073668; called by muse, mutect2, varscan2
- FAT3 | c.6020T>C p.V2007A | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs563450153, COSV53073679, COSV53109706; called by muse, mutect2, varscan2
- FBXO24 | c.1192G>A p.G398R (on ENST00000241071 / NM_033506.3; = p.G436R on NM_012172.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as rs745771512, COSV99575105; called by muse, mutect2, varscan2
- FBXO24 | c.1193G>A p.G398E (on ENST00000241071 / NM_033506.3; = p.G436E on NM_012172.5) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV99575110; called by muse, mutect2, varscan2
- FBXO40 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV57521765; called by muse, mutect2, varscan2
- FGD1 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64308037; called by muse, mutect2, varscan2
- FLG | c.8395G>A p.G2799R | Missense Mutation (SNP) | VAF 196/961 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs1426934666, COSV64236086; called by muse, mutect2, varscan2
- FRMD7 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1263577814, COSV53744490; called by muse, mutect2, varscan2
- GABRA1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs775157869, COSV50098608; called by muse, mutect2, varscan2
- GMIP | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1187549053, COSV52554067; called by muse, mutect2, varscan2
- GRIP1 | c.1585G>A p.G529R (on ENST00000359742 / NM_001379345.1; = p.G477R on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54014803; called by muse, mutect2, varscan2
- HCK | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52940118; called by muse, mutect2, varscan2
- HMGA2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs779988617, COSV63589423; called by muse, mutect2, varscan2
- HTR3E | c.1102G>A p.E368K (on ENST00000415389 / NM_001256613.1; = p.E383K on NM_182589.2) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.047); catalogued as COSV58945796; called by muse, mutect2
- IL1RL1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.253); catalogued as COSV52111916; called by muse, mutect2, varscan2
- IL26 | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV57488224; called by muse, mutect2, varscan2
- IMPG1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772872123, COSV64054037; called by muse, mutect2, varscan2
- INPP5F | c.2807C>T p.P936L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV62819530; called by muse, mutect2, varscan2
- KBTBD8 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.122); catalogued as COSV55126392; called by muse, mutect2, varscan2
- KCND3 | c.1907C>G p.P636R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100136939; called by muse, mutect2, varscan2
- KCND3 | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.106); catalogued as COSV100136941; called by muse, mutect2, varscan2
- KCNH3 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.184); catalogued as COSV99234917; called by muse, mutect2
- KCNH3 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.096); catalogued as COSV99234920; called by muse, mutect2
- KCNK13 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56410433; called by muse, mutect2, varscan2
- KCNQ3 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs756976785, COSV66463404; called by muse, mutect2, varscan2
- KDM2B | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV65637968; called by muse, mutect2
- KNSTRN | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51103388, COSV51103522; called by muse, mutect2, varscan2
- KRT37 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.038); catalogued as COSV56656757; called by muse, mutect2, varscan2
- KRT8 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as rs772599190, COSV53175868; called by muse, mutect2, varscan2
- L1CAM | c.3725A>G p.D1242G | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV62826681; called by muse, mutect2, varscan2
- LPL | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV60929876; called by muse, mutect2, varscan2
- LRP12 | c.1448A>G p.E483G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.5); catalogued as COSV52625429; called by muse, mutect2, varscan2
- MACC1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV60540713; called by muse, mutect2, varscan2
- MAP4K4 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 17/285 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV56324534; called by muse, mutect2
- MAPKBP1 | c.4094C>T p.P1365L (on ENST00000456763 / NM_001128608.2; = p.P1359L on NM_014994.3) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52957921; called by muse, mutect2, varscan2
- MARCHF10 | c.1241G>C p.G414A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV60885005; called by muse, mutect2, varscan2
- MARCO | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs761681020, COSV59051485; called by muse, mutect2, varscan2
- METTL21C | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765543295, COSV57432040; called by muse, mutect2, varscan2
- MGA | c.3073C>T p.L1025F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54948256; called by muse, mutect2, varscan2
- MGAM | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV72073548; called by muse, mutect2, varscan2
- MRPL24 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100625656; called by muse, mutect2, varscan2
- MRPL24 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100625657; called by muse, mutect2, varscan2
- MTCL1 | c.2480C>T p.T827M (on ENST00000306329 / NM_001378206.1; = p.T467M on NM_015210.4) | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs147236744; called by muse, mutect2, varscan2
- MUC16 | c.12482C>T p.S4161F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); catalogued as rs1442590851, COSV67443051; called by muse, mutect2, varscan2
- MYH2 | c.5608C>T p.L1870F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55431115; called by muse, mutect2
- MYH8 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1166542049, COSV67959411; called by muse, mutect2, varscan2
- MYO18B | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs865998147, COSV59124748; called by muse, mutect2, varscan2
- MYOF | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs1450476124, COSV63700046; called by muse, mutect2, varscan2
- NAV3 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs766043128, COSV57060537, COSV99031157; called by muse, mutect2, varscan2
- NEB | c.3521C>T p.A1174V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50807223; called by muse, mutect2, varscan2
- NIN | c.5740C>T p.Q1914* (on ENST00000382041 / NM_182946.1; = p.Q1201* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | catalogued as COSV55379656; called by muse, mutect2, varscan2
- NLRP1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1169457871, COSV52557974; called by muse, mutect2, varscan2
- NLRP11 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1568629768, COSV100789730, COSV64085509; called by muse, mutect2, varscan2
- NLRP8 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as COSV52583076; called by muse, mutect2, varscan2
- NOMO1 | c.2389G>T p.G797W | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55056880; called by muse, mutect2, varscan2
- NPTX2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as rs1257240079, COSV55716108; called by muse, mutect2, varscan2
- OR2J2 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.485); catalogued as COSV65847689; called by muse, mutect2, varscan2
- OR4A15 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.452); catalogued as rs200450197, COSV59033519; called by muse, mutect2, varscan2
- OR4C6 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.347); catalogued as rs148830288; called by muse, mutect2, varscan2
- OR52L1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV59985605; called by muse, mutect2, varscan2
- OR6C65 | c.596T>C p.L199S | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.017); catalogued as COSV65568103, COSV65568419, COSV65569576; called by muse, mutect2, varscan2
- OR8B3 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.385); catalogued as COSV63541226; called by muse, mutect2, varscan2
- OR8B8 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV60143645; called by muse, mutect2, varscan2
- OTOA | c.3459G>A p.W1153* (on ENST00000286149; = p.W1139* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs144955773; called by muse, mutect2, varscan2
- OTX2 | c.845C>T p.S282F (on ENST00000408990 / NM_172337.3; = p.S290F on NM_021728.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV59765233; called by muse, mutect2, varscan2
- PCLO | c.3863G>A p.G1288E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370173546; called by muse, mutect2, varscan2
- PCNT | c.5471T>A p.L1824H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64024801; called by muse, mutect2, varscan2
- PCSK6 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV59338030; called by muse, mutect2, varscan2
- PDE1C | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58502763, COSV58513454; called by muse, mutect2, varscan2
- PDLIM5 | c.1284-1G>A p.X428_splice | Splice Site (SNP) | VAF 21/54 reads (39%) | catalogued as COSV58744951; called by muse, mutect2, varscan2
- PDZD4 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as COSV51245270; called by muse, mutect2, varscan2
- PFKFB4 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | PolyPhen possibly damaging (0.832); catalogued as rs554595347, COSV51679421; called by muse, mutect2, varscan2
- PIANP | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.108); catalogued as COSV57707488; called by muse, mutect2, varscan2
- PID1 | c.718G>A p.E240K (on ENST00000354069 / NM_001330156.1; = p.E238K on NM_017933.5) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV62472286; called by muse, mutect2, varscan2
- PKLR | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV61360273; called by muse, mutect2, varscan2
- POTEF | c.2068C>T p.L690F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV62539553; called by muse, mutect2, varscan2
- PPIL2 | c.634T>A p.Y212N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.06); catalogued as COSV58604607; called by muse, mutect2, varscan2
- PPP1R3C | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); catalogued as COSV53287549; called by muse, mutect2, varscan2
- PRAMEF20 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs202075096; called by muse, mutect2, varscan2
- PRRX1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.994); catalogued as rs766027745, COSV53410751; called by muse, mutect2, varscan2
- PRUNE2 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs763455397, COSV65026376; called by muse, mutect2, varscan2
- PSG5 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV61653421; called by muse, mutect2, varscan2
- PTPRT | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61958907; called by muse, mutect2, varscan2
- RAB3IP | c.181C>T p.P61S (on ENST00000550536 / NM_175623.4; = p.P45S on NM_022456.5) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.419); catalogued as rs1440162114, COSV56081589; called by muse, mutect2, varscan2
- RAD9B | c.1176C>A p.F392L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100799304, COSV62825712; called by muse, mutect2, varscan2
- RASGRP4 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53093929, COSV99498369; called by muse, mutect2, varscan2
- RBL2 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50872813, COSV50883687; called by muse, mutect2, varscan2
- RBM27 | c.1607T>G p.V536G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV54587093; called by muse, mutect2, varscan2
- RGS7BP | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1433978701, COSV61833341; called by muse, mutect2, varscan2
- RINL | c.892C>T p.P298S (on ENST00000591812 / NM_001195833.2; = p.P184S on NM_198445.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.554); catalogued as COSV100531041; called by muse, mutect2, varscan2
- RNF32 | c.661A>G p.R221G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58730931; called by muse, mutect2, varscan2
- ROR1 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 46/111 reads (41%) | catalogued as COSV64283726; called by muse, mutect2, varscan2
- RP1 | c.3419G>A p.G1140E | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.05); catalogued as rs1025535519, COSV55109596; called by muse, mutect2, varscan2
- RYR3 | c.10184G>A p.R3395Q (on ENST00000389232; = p.R3396Q on NM_001036.6) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771747010, COSV66777075; called by muse, mutect2, varscan2
- SECTM1 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.404); catalogued as COSV53938187; called by muse, mutect2, varscan2
- SERPINI1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55507755; called by muse, mutect2, varscan2
- SH3PXD2A | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63507700; called by muse, mutect2, varscan2
- SH3RF2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs370632302; called by muse, mutect2
- SHROOM4 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV56783912; called by muse, mutect2, varscan2
- SIM1 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.442); catalogued as rs149460504; called by muse, mutect2, varscan2
- SIPA1L1 | c.3347C>T p.S1116F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV62168263; called by muse, mutect2, varscan2
- SLC13A1 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs766486753, COSV52007865; called by muse, mutect2, varscan2
- SLC13A4 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as rs927266787, COSV62459835; called by muse, mutect2, varscan2
- SLC17A8 | c.497T>C p.L166S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs762752502, COSV60121733; called by muse, mutect2, varscan2
- SLC28A2 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV61663158; called by muse, mutect2, varscan2
- SLC39A12 | c.1571T>A p.I524K (on ENST00000377369 / NM_001145195.2; = p.I487K on NM_152725.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV66194738; called by muse, mutect2, varscan2
- SLFN13 | c.2264A>G p.N755S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV53192172, COSV99539757; called by muse, mutect2, varscan2
- SNCAIP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as rs534709742, COSV54401767; called by muse, mutect2, varscan2
- SPAM1 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV56141082; called by muse, mutect2, varscan2
- SPEG | c.4810C>T p.H1604Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1273077577, COSV56662624; called by muse, mutect2, varscan2
- STAT4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1437812400, COSV61827746; called by muse, mutect2, varscan2
- STEAP4 | c.836T>G p.F279C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57327948; called by muse, mutect2, varscan2
- STPG4 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV54277812; called by muse, mutect2, varscan2
- SUV39H2 | c.401G>A p.R134K (on ENST00000354919 / NM_001193424.2; = p.R74K on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV57952312, COSV57954769; called by muse, mutect2, varscan2
- TAF4B | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as rs1270870526, COSV52301072; called by muse, mutect2, varscan2
- TAFA1 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs748165508, COSV72036920; called by muse, mutect2, varscan2
- TANC1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55082575; called by muse, mutect2, varscan2
- TANC2 | c.5161C>T p.Q1721* | Nonsense Mutation (SNP) | VAF 41/159 reads (26%) | catalogued as COSV67329702; called by muse, mutect2, varscan2
- TBRG4 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs747356200, COSV51831715; called by muse, mutect2, varscan2
- TBX18 | c.1044G>A p.W348* | Nonsense Mutation (SNP) | VAF 43/73 reads (59%) | catalogued as COSV63735969; called by muse, mutect2, varscan2
- TEP1 | c.4676C>T p.S1559L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1286514370, COSV52987795; called by muse, mutect2, varscan2
- THSD7B | c.4340G>A p.R1447Q (on ENST00000272643; = p.R1445Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267598902, COSV55651965; called by muse, mutect2, varscan2
- TNFRSF13B | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV55426509; called by muse, mutect2, varscan2
- TPRG1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs759000542, COSV61463190; called by muse, mutect2, varscan2
- TRPM8 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375003857, COSV61220464; called by muse, mutect2, varscan2
- TTN | c.11404G>A p.E3802K (on ENST00000591111; = p.E3756K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100600519; called by muse, mutect2, varscan2
- TTN | c.5444G>A p.R1815K (on ENST00000591111; = p.R1769K on NM_003319.4) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | PolyPhen benign (0.015); catalogued as COSV59874544, COSV60371008; called by muse, mutect2, varscan2
- TUBB4A | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51152198; called by muse, mutect2, varscan2
- USHBP1 | c.1046+1G>A p.X349_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53102189; called by muse, mutect2, varscan2
- USP36 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61750056; called by muse, mutect2, varscan2
- VIPR2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51103196; called by muse, mutect2, varscan2
- ZDHHC8 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1305261805, COSV57709203; called by muse, mutect2, varscan2
- ZNF215 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV53491532; called by muse, mutect2, varscan2
- ZNF366 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV59213614; called by muse, mutect2, varscan2
- ZNF569 | c.1343T>C p.I448T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.969); catalogued as COSV57593402; called by muse, mutect2, varscan2
- ZNF586 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs751977813, COSV66972118; called by muse, mutect2, varscan2
- AMZ2 | c.545_557del p.D182Vfs*8 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- ANKRD20A4P | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- FER1L6 | c.2620_2626del p.N874Cfs*13 | Frame Shift Del (DEL) | VAF 47/221 reads (21%) | called by mutect2, pindel, varscan2
- MEPE | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.096); called by muse, mutect2
- SOS2 | c.2260_2266del p.S754Lfs*20 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- SV2B | c.1336_1337delinsG p.N446Vfs*10 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | called by pindel, varscan2*
- ABCC8 | c.4719C>T p.F1573= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs772045105, COSV56845900; called by muse, mutect2, varscan2
- ABR | c.1227G>A p.K409= (on ENST00000302538 / NM_021962.5; = p.K372= on NM_001092.5) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV52141220; called by muse, mutect2, varscan2
- ACKR3 | c.51C>T p.I17= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV56020408; called by muse, mutect2, varscan2
- ADGRV1 | c.1062T>C p.I354= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV67978025; called by muse, mutect2, varscan2
- AMER3 | c.1002G>A p.G334= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV58465034; called by muse, mutect2, varscan2
- ANKRD1 | c.288G>A p.R96= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1430389173, COSV63310865; called by muse, mutect2
- ANKRD34B | c.834C>T p.S278= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1234236927, COSV58613317; called by muse, mutect2, varscan2
- APOB | c.12738C>T p.F4246= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV51922286; called by muse, mutect2, varscan2
- APOBEC2 | c.57G>A p.E19= | Silent (SNP) | VAF 58/87 reads (67%) | catalogued as COSV55141933; called by muse, mutect2, varscan2
- ARAP3 | c.211C>T p.L71= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV99499447, COSV99499681; called by muse, mutect2
- ARAP3 | c.210C>T p.S70= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99499448; called by muse, mutect2
- ARHGAP26 | c.2052C>T p.S684= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV50824053; called by muse, mutect2, varscan2
- ARSB | c.1302A>G p.R434= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53718706; called by muse, mutect2, varscan2
- B3GALT2 | c.1116G>A p.S372= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs896980217, COSV66463746; called by muse, mutect2, varscan2
- C1orf127 | c.1452G>A p.S484= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs753074905, COSV100983433, COSV65436661; called by muse, mutect2, varscan2
- CBLC | c.942C>T p.T314= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV54321281; called by muse, mutect2, varscan2
- CDC42BPB | c.3382C>T p.L1128= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV63473753; called by muse, mutect2, varscan2
- CDH24 | c.897G>A p.L299= | Silent (SNP) | VAF 75/150 reads (50%) | catalogued as COSV52973026; called by muse, mutect2, varscan2
- CFAP45 | c.405G>A p.K135= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV63647907; called by muse, mutect2, varscan2
- CHST4 | c.600C>T p.I200= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs752000094, COSV58296411; called by muse, mutect2, varscan2
- CLU | c.981C>T p.L327= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs762416469, COSV57065457; called by muse, mutect2, varscan2
- COG5 | c.831G>A p.V277= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV51742290; called by muse, mutect2, varscan2
- CSMD2 | c.1263C>T p.F421= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs867435567, COSV53876622; called by muse, mutect2, varscan2
- DCC | c.1764G>A p.L588= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV59083001; called by muse, mutect2
- DIO3 | c.903C>T p.P301= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100832023, COSV63772979; called by muse, mutect2, varscan2
- DLGAP4 | c.2895G>A p.R965= (on ENST00000339266 / NM_001365621.1; = p.R962= on NM_014902.6) | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV59414157; called by muse, mutect2, varscan2
- DNAH3 | c.3417G>A p.Q1139= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV54502420; called by muse, mutect2
- DUOX2 | c.2547G>A p.V849= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV66530475; called by muse, mutect2, varscan2
- EPHA8 | c.2463G>T p.V821= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV51262424; called by muse, mutect2, varscan2
- EVPL | c.3078C>T p.P1026= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs371295003, COSV56907142; called by muse, mutect2, varscan2
- FCRL5 | c.729G>A p.P243= | Silent (SNP) | VAF 121/229 reads (53%) | catalogued as rs752945522, COSV62511099; called by muse, mutect2, varscan2
- FIGN | c.1872C>T p.I624= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs377530148, COSV60769445; called by muse, mutect2, varscan2
- FRAS1 | c.9561G>A p.K3187= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV53587555, COSV53607536; called by muse, mutect2, varscan2
- GAL3ST2 | c.9C>T p.S3= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV51949348; called by muse, mutect2, varscan2
- GIMAP6 | c.831G>A p.K277= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs753577653, COSV61032391, COSV61034135; called by muse, mutect2, varscan2
- GPN2 | c.714C>T p.I238= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs201547465, COSV64651537; called by muse, mutect2, varscan2
- GRID2 | c.1956C>T p.L652= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs370183875; called by muse, mutect2, varscan2
- GRIN2A | c.3135C>T p.S1045= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV58019187; called by muse, mutect2, varscan2
- GYPA | c.381T>A p.P127= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV51619263; called by muse, mutect2, varscan2
- HECW1 | c.2544G>A p.V848= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV67821242; called by muse, mutect2, varscan2
- HILPDA | c.78C>T p.S26= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV57555984; called by muse, mutect2, varscan2
- HNRNPL | c.1056C>T p.H352= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- HTR3A | c.1027C>T p.L343= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV55467843; called by muse, mutect2, varscan2
- IPO4 | c.1359C>T p.H453= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV55777799; called by muse, mutect2, varscan2
- ITPR3 | c.754C>T p.L252= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV65405315; called by muse, mutect2, varscan2
- JAG1 | c.2442G>A p.G814= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs745496042, COSV54753081; called by mutect2, varscan2
- KIF26A | c.1977C>T p.A659= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1427272129, COSV59464362; called by muse, mutect2, varscan2
- KMT2D | c.4164G>A p.R1388= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99978734; called by muse, mutect2, varscan2
- KSR2 | c.2268C>T p.I756= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV56665231, COSV56677971; called by muse, mutect2, varscan2
- LAMB4 | c.4881G>A p.L1627= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs566642626, COSV52713071; called by muse, mutect2, varscan2
- LRRC2 | c.405C>T p.I135= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV56124808; called by muse, mutect2, varscan2
- LRRC42 | c.240G>A p.G80= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs1361066636, COSV59960019; called by muse, mutect2, varscan2
- MC3R | c.381C>T p.S127= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs768973003, COSV54762947; called by muse, mutect2, varscan2
- MICAL2 | c.3801G>A p.K1267= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV56284074; called by muse, mutect2, varscan2
- MYH13 | c.1086G>A p.G362= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs919348180, COSV52820322; called by muse, mutect2, varscan2
- MYH15 | c.4548C>T p.N1516= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV56304016; called by muse, mutect2, varscan2
- MYO3B | c.3567G>A p.E1189= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV58693585; called by muse, mutect2, varscan2
- NOTCH2 | c.4131C>T p.G1377= | Silent (SNP) | VAF 52/80 reads (65%) | catalogued as COSV56680933; called by muse, mutect2, varscan2
- NRDE2 | c.942T>C p.F314= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV62962039; called by muse, mutect2, varscan2
- OR10X1 | c.867C>T p.V289= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV63766880; called by muse, mutect2, varscan2
- OR10Z1 | c.594G>A p.R198= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs1460982717, COSV63523780; called by muse, mutect2, varscan2
- OR11H1 | c.486C>T p.I162= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99421614; called by mutect2, varscan2
- OR2A14 | c.918G>A p.K306= | Silent (SNP) | VAF 62/201 reads (31%) | catalogued as COSV68717870; called by muse, mutect2, varscan2
- OR2T5 | c.198C>T p.F66= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100822170; called by mutect2, varscan2
- OR4K5 | c.765C>T p.I255= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as rs762470512, COSV60002223; called by muse, mutect2, varscan2
- OR5AR1 | c.645C>T p.F215= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs867148047, COSV57252688; called by muse, mutect2, varscan2
- OR5B17 | c.654C>T p.F218= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV62159817; called by muse, mutect2, varscan2
- OR5J2 | c.99G>A p.V33= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as COSV56620132; called by muse, mutect2, varscan2
- OR6C3 | c.177C>T p.F59= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV65570586; called by muse, mutect2, varscan2
- PAK5 | c.1962G>A p.R654= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs1004349087, COSV62020486, COSV62032676; called by muse, mutect2, varscan2
- PCDH15 | c.4758G>A p.R1586= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV57260794; called by muse, mutect2, varscan2
- PCDHA7 | c.318G>A p.L106= | Silent (SNP) | VAF 43/254 reads (17%) | catalogued as COSV65341642; called by muse, mutect2, varscan2
- PCDHA8 | c.1410G>A p.P470= | Silent (SNP) | VAF 47/59 reads (80%) | catalogued as rs202126810, COSV65334668, COSV65339563; called by muse, mutect2, varscan2
- PCDHA9 | c.318G>A p.L106= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV65323176; called by muse, mutect2, varscan2
- PCP4 | c.165G>A p.K55= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV60786026; called by muse, mutect2, varscan2
- PHC1 | c.1221C>T p.F407= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV70417489; called by mutect2, varscan2
- PLEK | c.144C>T p.I48= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs368479855, COSV52250409; called by muse, mutect2, varscan2
- PLEKHG4 | c.1065C>T p.I355= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs769349564, COSV64611697; called by muse, mutect2, varscan2
- PTPRU | c.3819C>T p.I1273= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs375146224; called by muse, mutect2, varscan2
- RINL | c.891C>T p.D297= (on ENST00000591812 / NM_001195833.2; = p.D183= on NM_198445.4) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs905274016, COSV100531043; called by muse, mutect2, varscan2
- RNF213 | c.10263C>T p.S3421= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV60389556; called by mutect2, varscan2
- SCRN1 | c.75G>A p.G25= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV54128152; called by muse, mutect2, varscan2
- SGSM1 | c.1332G>A p.V444= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV68508627; called by muse, mutect2, varscan2
- SHE | c.348G>A p.A116= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV59070716; called by muse, mutect2
- SIGLEC6 | c.840C>T p.P280= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV58431800; called by muse, mutect2, varscan2
- SLC25A28 | c.744C>T p.F248= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV65125154; called by muse, mutect2, varscan2
- SLC35F3 | c.114C>T p.L38= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV64022608; called by muse, mutect2, varscan2
- SLC40A1 | c.174C>T p.L58= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV53721766; called by muse, mutect2, varscan2
- SLFN5 | c.867C>A p.L289= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV55479717; called by muse, mutect2, varscan2
- SPHKAP | c.2979G>A p.R993= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV60867997; called by muse, mutect2, varscan2
- STAT2 | c.441C>T p.S147= | Silent (SNP) | VAF 94/262 reads (36%) | catalogued as COSV58474152; called by muse, mutect2, varscan2
- STK38 | c.1203C>T p.I401= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV57707426; called by mutect2, varscan2
- SYNE1 | c.8385G>A p.A2795= (on ENST00000367255 / NM_182961.4; = p.A2802= on NM_033071.3) | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs267600863, COSV54901077; called by muse, mutect2, varscan2
- SYNE2 | c.13146C>T p.F4382= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV59939069; called by muse, mutect2, varscan2
- TAS2R3 | c.168C>T p.I56= | Silent (SNP) | VAF 64/255 reads (25%) | catalogued as COSV56091554; called by muse, mutect2, varscan2
- TECPR2 | c.213C>T p.N71= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV63968889; called by muse, mutect2, varscan2
- UGT3A2 | c.1038G>A p.V346= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV56928068; called by muse, mutect2, varscan2
- VCAM1 | c.1482C>T p.F494= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs368828382; called by muse, mutect2, varscan2
- XIRP2 | c.678C>T p.F226= (on ENST00000628543; = p.F401= on NM_152381.6) | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs935432440, COSV54681208, COSV99739318; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIRP2 | c.4107G>A p.K1369= (on ENST00000628543; = p.K1544= on NM_152381.6) | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV54681218; called by muse, mutect2, varscan2
- ZDHHC8 | c.1083C>T p.F361= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV57710390; called by muse, mutect2, varscan2
- ZNF792 | c.528C>T p.P176= | Silent (SNP) | VAF 77/239 reads (32%) | catalogued as rs182386803, COSV68692669; called by muse, mutect2, varscan2
- COPS9 | chr2:240136314 C>T | 5'Flank (SNP) | VAF 4/13 reads (31%) | catalogued as COSV56227738; called by muse, mutect2
- FAM169B | n.594C>T | RNA (SNP) | VAF 11/24 reads (46%) | catalogued as rs1198320339, COSV60567859; called by muse, mutect2, varscan2
- HEXA | c.*2C>T | 3'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99173690; called by muse, mutect2, varscan2
- SPEN | c.404+1245C>T | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as COSV101005065; called by muse, mutect2
